Somatic mutation profile of tumor specimen TCGA-63-7020-01A (aliquot TCGA-63-7020-01A-11D-1945-08) from TCGA case TCGA-63-7020, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-7020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b23a544-2bee-43c5-a117-3e51c762b3b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-7020-10A (Blood Derived Normal), aliquot TCGA-63-7020-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80b96360-5205-42c8-9a50-3eff25211337

The open-access MAF lists 203 somatic variants for this specimen: 156 protein-altering or splice-affecting, 37 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 37, Nonsense Mutation 9, Splice Site 7, Frame Shift Del 5, RNA 5, Splice Region 4, Intron 3, Frame Shift Ins 3, 3'Flank 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs786202082, CD098502, COSV52704969, COSV52749634, COSV52761908, COSV52834111; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101295902; called by muse, mutect2, varscan2
- ABCC8 | c.2563C>A p.P855T | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773186703, COSV100217165; called by muse, mutect2, varscan2
- ADCY10 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as COSV100896821; called by muse, mutect2, varscan2
- APOL4 | c.557G>T p.G186V (on ENST00000352371 / NM_145660.2; = p.G183V on NM_030643.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100274107; called by muse, mutect2, varscan2
- ARID4A | c.3016G>T p.A1006S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.257); catalogued as COSV100794201; called by muse, mutect2, varscan2
- ASB5 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1333462515, COSV99641605; called by muse, mutect2, varscan2
- ATP1A2 | c.495+2T>C p.X165_splice | Splice Site (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100767804; called by muse, mutect2, varscan2
- ATP5F1B | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100008095, COSV56261268; called by muse, mutect2, varscan2
- AURKC | c.344G>T p.R115L (on ENST00000302804 / NM_001015878.2; = p.R81L on NM_003160.3) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100248666, COSV100248825; called by muse, mutect2, varscan2
- BARD1 | c.1978A>T p.S660C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99638570; called by muse, mutect2, varscan2
- C17orf97 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100789335; called by muse, varscan2
- CACNA1S | c.4427A>T p.K1476M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100754947; called by muse, mutect2, varscan2
- CACNA1S | c.3053A>C p.Q1018P | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.646); catalogued as COSV100754948; called by muse, mutect2, varscan2
- CACNG7 | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV99711990; called by muse, mutect2, varscan2
- CBFA2T3 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs960207100, COSV99241693; called by muse, varscan2
- CC2D2A | c.4776A>C p.E1592D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100377846; called by muse, mutect2, varscan2
- CCNB1IP1 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.556); catalogued as COSV100738556; called by muse, mutect2
- CHD6 | c.5074A>G p.I1692V | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs767959197, COSV100950926; called by muse, mutect2, varscan2
- CILP | c.1948G>T p.D650Y | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99973310; called by muse, mutect2, varscan2
- CNTNAP4 | c.1748C>A p.A583D | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100271073; called by muse, mutect2, varscan2
- CRP | c.596G>T p.S199I | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.783); catalogued as COSV99660566; called by muse, mutect2, varscan2
- CSMD3 | c.10816C>A p.L3606I (on ENST00000297405 / NM_001363185.1; = p.L3437I on NM_052900.3) | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99832803; called by muse, varscan2
- CSMD3 | c.5009G>A p.S1670N (on ENST00000297405 / NM_001363185.1; = p.S1566N on NM_052900.3) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV99832807; called by muse, mutect2, varscan2
- CSMD3 | c.4872T>A p.Y1624* (on ENST00000297405 / NM_001363185.1; = p.Y1520* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV99832811; called by muse, mutect2, varscan2
- CTNNA2 | c.2609A>T p.K870I (on ENST00000402739 / NM_001282597.3; = p.K822I on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100560328; called by muse, mutect2, varscan2
- DCDC1 | c.4828G>A p.E1610K (on ENST00000597505 / NM_001367979.1; = p.E717K on NM_020869.3) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs545158980, COSV100360476; called by muse, mutect2, varscan2
- DDB1 | c.2070-1G>T p.X690_splice | Splice Site (SNP) | VAF 33/109 reads (30%) | catalogued as COSV100074549; called by muse, mutect2, varscan2
- DDR2 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63370699, COSV63375038; called by muse, mutect2, varscan2
- DIDO1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99825657; called by muse, mutect2, varscan2
- DMD | c.3787G>C p.E1263Q | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV63757016; called by muse, mutect2, varscan2
- DNAH8 | c.7753C>A p.R2585S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544824; called by muse, mutect2, varscan2
- DNAH9 | c.2263G>T p.E755* | Nonsense Mutation (SNP) | VAF 36/78 reads (46%) | catalogued as COSV99305609; called by muse, mutect2, varscan2
- DPP3 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100855579; called by muse, mutect2, varscan2
- DPP3 | c.1894G>T p.G632W | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100855580; called by muse, mutect2, varscan2
- DUSP26 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56361889; called by muse, mutect2, varscan2
- EPGN | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.189); catalogued as COSV100141416; called by muse, mutect2, varscan2
- F5 | c.6610A>T p.I2204F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100889076; called by muse, mutect2, varscan2
- FAM135B | c.3143C>A p.P1048H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV99423187; called by muse, mutect2, varscan2
- FAM227B | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs748816760, COSV100174924; called by muse, mutect2, varscan2
- FAN1 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV62950572; called by muse, mutect2, varscan2
- FANCM | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99360899; called by muse, mutect2
- FAT3 | c.6171C>A p.S2057R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as COSV99035414; called by muse, mutect2, varscan2
- FBN3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs528849979, COSV54464560; called by muse, mutect2, varscan2
- FLCN | c.907dup p.E303Gfs*3 | Frame Shift Ins (INS) | VAF 69/198 reads (35%) | catalogued as CI1511729; called by mutect2, pindel, varscan2
- FLNA | c.3068G>T p.G1023V | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.081); catalogued as rs1569551724, COSV100774657, COSV61048898; called by muse, mutect2, varscan2
- FMN2 | c.3677C>A p.P1226H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.084); catalogued as COSV100144768; called by muse, mutect2, varscan2
- GAD2 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1243932259, COSV99393155; called by muse, mutect2, varscan2
- GFPT2 | c.1535G>T p.R512I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs746813046, COSV53813748, COSV99517617; called by muse, mutect2, varscan2
- GPA33 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100901019; called by muse, mutect2, varscan2
- GPR137C | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100397575, COSV58704885; called by muse, mutect2, varscan2
- GSX2 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs762385629, COSV100482556; called by muse, mutect2, varscan2
- HAL | c.855C>A p.Y285* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as COSV99701379; called by muse, mutect2, varscan2
- IGF1 | c.579del p.G194Efs*8 | Frame Shift Del (DEL) | VAF 108/320 reads (34%) | catalogued as rs1565968684, COSV61032034; called by mutect2, pindel, varscan2
- IGHV4-61 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.165); catalogued as rs1488946076; called by muse, mutect2
- IL7R | c.537G>T p.T179= | Splice Region (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100285886, COSV57409931; called by muse, mutect2, varscan2
- IMPG1 | c.1611C>G p.S537R | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100886338; called by muse, mutect2, varscan2
- INTS13 | c.1564G>T p.G522C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99677341; called by muse, mutect2, varscan2
- IPO13 | c.2672C>G p.A891G | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV99664437; called by muse, mutect2, varscan2
- ITPRID1 | c.962G>T p.C321F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.711); catalogued as COSV100086289; called by muse, mutect2, varscan2
- KATNIP | c.3939G>C p.W1313C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850934; called by muse, mutect2, varscan2
- KDM5D | c.2077G>T p.D693Y | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100522205, COSV58735912; called by muse, mutect2, varscan2
- KIF20B | c.3091A>G p.N1031D (on ENST00000371728 / NM_001284259.2; = p.N991D on NM_016195.4) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99589916; called by muse, mutect2, varscan2
- KLHDC8B | c.543G>C p.G181= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100234178; called by muse, mutect2, varscan2
- KLHL1 | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100917178, COSV64782113; called by muse, mutect2, varscan2
- KLRF1 | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV54381493; called by muse, mutect2, varscan2
- KRT15 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs201164162; called by muse, mutect2, varscan2
- KRT31 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99289705; called by muse, mutect2, varscan2
- KRT4 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV99542869; called by muse, mutect2, varscan2
- KRT73 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99988485; called by muse, mutect2, varscan2
- KRT75 | c.470A>T p.N157I | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV99359389; called by muse, mutect2, varscan2
- KRTAP10-5 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs370129643, COSV100553262; called by muse, mutect2, varscan2
- LAMA3 | c.9860A>G p.N3287S (on ENST00000313654 / NM_198129.4; = p.N1678S on NM_000227.6) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.381); catalogued as COSV99334633; called by muse, mutect2, varscan2
- LAMA5 | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99439677; called by muse, mutect2, varscan2
- LIMD1 | c.1879T>C p.C627R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99836908; called by muse, mutect2, varscan2
- LRP12 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV99407621; called by muse, mutect2, varscan2
- LRRC31 | c.321T>C p.V107= | Splice Region (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99246652; called by muse, mutect2, varscan2
- MAGEL2 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.973); catalogued as rs755699846, COSV58566777, COSV58568348; called by mutect2, varscan2
- MGAM | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782122165, COSV72074717; called by muse, mutect2, varscan2
- MIEF1 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV100307653; called by muse, mutect2, varscan2
- MMEL1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781420673, COSV99983712; called by muse, mutect2, varscan2
- MOV10 | c.1679C>G p.A560G | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100659526; called by muse, mutect2, varscan2
- MPRIP | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs1198625632, COSV100505629; called by muse, mutect2, varscan2
- MRGPRX4 | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100049711; called by muse, mutect2, varscan2
- MUC5B | c.8921C>A p.T2974N | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV101500282; called by muse, mutect2, varscan2
- MYBPC3 | c.1411G>C p.V471L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV99920252; called by muse, mutect2, varscan2
- MYCBP2 | c.6745A>G p.I2249V (on ENST00000357337; = p.I2287V on NM_015057.5) | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100630190; called by muse, mutect2, varscan2
- MYL2 | c.332A>C p.K111T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99960739; called by muse, mutect2, varscan2
- NAALADL2 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as rs755067572, COSV101435756; called by muse, varscan2
- NDNF | c.1136A>G p.H379R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as COSV101113158; called by muse, mutect2, varscan2
- NEU2 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs755571923, COSV52092434; called by muse, mutect2, varscan2
- NF1 | c.7879G>T p.V2627L (on ENST00000358273 / NM_001042492.3; = p.V2606L on NM_000267.3) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV100646833; called by muse, mutect2, varscan2
- NGEF | c.1057T>A p.Y353N | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.812); catalogued as COSV99889009; called by muse, mutect2, varscan2
- NMBR | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV57801511, COSV57803903; called by muse, mutect2, varscan2
- OPCML | c.401-2A>T p.X134_splice | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100100697; called by muse, mutect2, varscan2
- OPRL1 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100402064; called by muse, mutect2, varscan2
- OR10A6 | c.585T>A p.F195L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.996); catalogued as COSV100564278; called by muse, mutect2, varscan2
- OR4D2 | c.870G>T p.R290S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1440498481, COSV101613853, COSV73459698; called by muse, mutect2, varscan2
- OR4N5 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 125/332 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100374093; called by muse, mutect2, varscan2
- OR52N2 | c.253T>C p.C85R | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100396112; called by muse, mutect2
- OR5A1 | c.546C>A p.C182* | Nonsense Mutation (SNP) | VAF 38/240 reads (16%) | catalogued as COSV100118347, COSV57375591; called by muse, mutect2, varscan2
- OR8B2 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as rs1323506354, COSV100899387, COSV66665503; called by muse, varscan2
- OR8K1 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs769004561, COSV54401922; called by muse, mutect2, varscan2
- PARP6 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99535995; called by muse, mutect2, varscan2
- PARP8 | c.2173G>T p.A725S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99891142; called by muse, mutect2, varscan2
- PDLIM1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100267757; called by muse, mutect2, varscan2
- PELO | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.37); catalogued as COSV99251232; called by muse, mutect2, varscan2
- PIK3AP1 | c.1456C>A p.R486S | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100225724, COSV59535977; called by muse, mutect2, varscan2
- PLEKHA5 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as rs771443913, COSV100163947, COSV104397600; called by muse, mutect2, varscan2
- PLXNB1 | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs781131965, COSV99602768; called by muse, mutect2, varscan2
- PLXND1 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs781053507, COSV60714467; called by muse, mutect2, varscan2
- POLD1 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101486832; called by muse, varscan2
- RAB3GAP1 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV99921009; called by muse, varscan2
- RAD51AP2 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV101208330, COSV67587549; called by muse, mutect2, varscan2
- RAPGEF1 | c.1709A>T p.Y570F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV100940484; called by muse, mutect2, varscan2
- RBPMS2 | c.201A>T p.R67S | Missense Mutation (SNP) | VAF 109/262 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV100264844; called by muse, mutect2, varscan2
- RECK | c.925T>C p.Y309H | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100937473; called by muse, mutect2, varscan2
- RELN | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV58986848, COSV59009383; called by muse, mutect2, varscan2
- RGS7 | c.336C>A p.T112= | Splice Region (SNP) | VAF 21/132 reads (16%) | catalogued as rs1365647897, COSV100466966; called by muse, mutect2, varscan2
- RNF111 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 35/161 reads (22%) | catalogued as COSV100789019; called by muse, mutect2, varscan2
- RNF144A | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100305590; called by muse, varscan2
- RNF40 | c.2447G>T p.G816V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV100222046; called by muse, mutect2, varscan2
- RPRML | c.200T>A p.V67E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100461940; called by muse, mutect2, varscan2
- RTN1 | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99955450; called by muse, mutect2, varscan2
- RYR3 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101212644; called by muse, mutect2
- SI | c.1399-1G>T p.X467_splice | Splice Site (SNP) | VAF 33/120 reads (28%) | catalogued as rs1387965890, COSV100015305; called by muse, mutect2, varscan2
- SLC39A2 | c.921G>T p.L307F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100068550; called by muse, mutect2, varscan2
- SLC43A3 | c.437A>C p.Q146P | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs550758492, COSV100725185; called by muse, mutect2, varscan2
- SLC8A3 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100776134; called by muse, mutect2, varscan2
- SNTG1 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as rs138942717, COSV52450226, COSV99383359; called by muse, mutect2, varscan2
- SORL1 | c.6187_6188del p.M2063Vfs*2 | Frame Shift Del (DEL) | VAF 23/156 reads (15%) | catalogued as rs765631255; called by mutect2, pindel, varscan2
- SVEP1 | c.2273A>G p.D758G | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.39); PolyPhen benign (0.182); catalogued as COSV57048375; called by muse, mutect2, varscan2
- SYT9 | c.1359C>G p.I453M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); catalogued as COSV100608031, COSV59624727; called by muse, mutect2
- TGM7 | c.558+1del p.X186_splice | Splice Site (DEL) | VAF 16/45 reads (36%) | catalogued as COSV71773022; called by mutect2, pindel, varscan2
- TNN | c.2392G>A p.D798N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53429761; called by muse, mutect2, varscan2
- TNR | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99689297; called by muse, mutect2
- TRIM49 | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV100316030, COSV61671630; called by muse, mutect2, varscan2
- TTN | c.23977T>C p.Y7993H (on ENST00000591111; = p.Y7066H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/104 reads (9%) | PolyPhen benign (0.071); catalogued as COSV100610304; called by muse, mutect2
- UBE2U | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV100934381; called by muse, mutect2, varscan2
- UNC119 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99256872; called by muse, mutect2, varscan2
- UVSSA | c.2036+2T>G p.X679_splice | Splice Site (SNP) | VAF 7/15 reads (47%) | catalogued as COSV101104423; called by muse, mutect2, varscan2
- VANGL1 | c.1314+2T>C p.X438_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100049090; called by muse, mutect2, varscan2
- VSX2 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763516064, COSV100001593, COSV56217132; called by muse, mutect2, varscan2
- ZBTB8A | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100331347; called by muse, mutect2, varscan2
- ZFHX4 | c.10733A>T p.D3578V | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99262033; called by muse, mutect2, varscan2
- ZNF551 | c.1639A>C p.I547L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV99989951; called by muse, mutect2, varscan2
- ZSCAN5B | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100627962; called by muse, mutect2, varscan2
- ABCB1 | c.3341del p.G1114Afs*33 | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | called by mutect2, pindel, varscan2
- EPYC | c.279dup p.D94* | Frame Shift Ins (INS) | VAF 14/97 reads (14%) | called by mutect2, pindel, varscan2
- FEM1B | c.922dup p.C308Lfs*2 | Frame Shift Ins (INS) | VAF 29/89 reads (33%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPL4 | c.816_821del p.L273_K274del | In Frame Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel
- TNP2 | c.38_66del p.T13Kfs*54 | Frame Shift Del (DEL) | VAF 60/200 reads (30%) | called by mutect2, pindel
- TRGV8 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USP51 | c.934_936del p.L312del | In Frame Del (DEL) | VAF 10/60 reads (17%) | called by pindel, varscan2
- ZNF648 | c.79del p.Q27Rfs*3 | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.1353C>T p.F451= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs1452989557, COSV66062953; called by muse, mutect2, varscan2
- ALDH3B2 | c.360C>A p.T120= | Silent (SNP) | VAF 98/258 reads (38%) | catalogued as COSV100824031; called by muse, mutect2, varscan2
- BRINP3 | c.1519C>A p.R507= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as COSV100818702, COSV66515003; called by muse, mutect2, varscan2
- CORO7 | c.2409G>T p.L803= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99227574; called by muse, mutect2, varscan2
- CRHR2 | c.720C>G p.V240= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100529956; called by muse, mutect2
- CROCC | c.3534G>C p.L1178= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100978194; called by muse, mutect2, varscan2
- DOCK5 | c.3507G>A p.K1169= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99376795; called by muse, varscan2
- ERVW-1 | c.69T>C p.P23= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV101423831; called by muse, mutect2, varscan2
- FLG | c.1647C>G p.T549= | Silent (SNP) | VAF 164/455 reads (36%) | catalogued as rs1321260379, COSV100911515; called by muse, mutect2, varscan2
- FLT1 | c.318C>T p.S106= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV99153545; called by muse, mutect2, varscan2
- FLVCR2 | c.186T>C p.S62= | Silent (SNP) | VAF 91/175 reads (52%) | catalogued as COSV99471254; called by muse, mutect2, varscan2
- GDPD1 | c.915T>C p.L305= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99405036; called by muse, mutect2, varscan2
- HSPA14 | c.585G>A p.V195= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs752242540, COSV101000659; called by muse, mutect2, varscan2
- ITGAL | c.2556C>A p.S852= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as COSV100776233; called by muse, mutect2, varscan2
- KAT6A | c.5601G>T p.A1867= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs140666969, COSV55902597; called by muse, mutect2, varscan2
- KCNB1 | c.207G>A p.L69= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100870448; called by muse, mutect2, varscan2
- MARF1 | c.3675C>T p.I1225= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs368752613; called by muse, mutect2, varscan2
- MELTF | c.1245C>A p.V415= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV99586124; called by muse, mutect2, varscan2
- METTL21C | c.666A>T p.A222= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV99940028; called by muse, mutect2, varscan2
- MPO | c.1704C>A p.I568= | Silent (SNP) | VAF 64/147 reads (44%) | catalogued as COSV99228729, COSV99228988; called by muse, mutect2, varscan2
- OR2M4 | c.687C>A p.G229= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100141168; called by muse, mutect2, varscan2
- OR4A5 | c.147C>G p.A49= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100157074, COSV60522663; called by muse, mutect2, varscan2
- OR4C3 | c.156G>T p.T52= | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- OR5AP2 | c.660C>G p.V220= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV100266182; called by muse, mutect2, varscan2
- PEG3 | c.3900C>T p.H1300= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs571070040, COSV55628355, COSV55652772; called by muse, mutect2, varscan2
- PIP5K1B | c.144A>T p.P48= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV99598649; called by muse, mutect2, varscan2
- RASGRF1 | c.1428G>A p.R476= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV101369618; called by muse, mutect2, varscan2
- RNF26 | c.657C>T p.L219= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs1196256613, COSV100264790; called by muse, mutect2, varscan2
- SCARF2 | c.2133G>T p.A711= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99839163, COSV99839266; called by muse, mutect2, varscan2
- SEC23B | c.1080G>A p.L360= | Silent (SNP) | VAF 11/301 reads (4%) | called by muse, mutect2
- SIGLEC9 | c.1149C>A p.G383= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV99142544; called by muse, mutect2, varscan2
- SLC4A8 | c.1909A>C p.R637= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100176751; called by muse, mutect2, varscan2
- SNED1 | c.3318T>C p.P1106= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100122594; called by muse, mutect2
- TAF1L | c.975C>A p.L325= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV99644564; called by muse, mutect2, varscan2
- ZNF536 | c.2154C>T p.S718= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100835157; called by muse, mutect2, varscan2
- ZNF572 | c.1236C>T p.Y412= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV100073935; called by muse, mutect2, varscan2
- ZNF639 | c.108T>A p.S36= | Silent (SNP) | VAF 64/174 reads (37%) | catalogued as COSV100418418; called by muse, mutect2, varscan2
- DCHS2 | n.2381G>T | RNA (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100251669; called by muse, mutect2, varscan2
- GCNT2 | c.926-35063T>C | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99399236; called by muse, mutect2, varscan2
- HTR2C | c.-80+16933C>A | Intron (SNP) | VAF 17/25 reads (68%) | catalogued as COSV99349118; called by muse, mutect2, varscan2
- MIR19B2 | n.52T>C | RNA (SNP) | VAF 38/60 reads (63%) | called by muse, mutect2, varscan2
- MIR655 | n.44C>T | RNA (SNP) | VAF 18/108 reads (17%) | catalogued as rs778280798; called by muse, mutect2, varscan2
- RUFY3 | chr4:70794875 A>G | 3'Flank (SNP) | VAF 44/91 reads (48%) | catalogued as COSV99887243; called by muse, mutect2, varscan2
- SSPOP | n.14014G>T | RNA (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100947319; called by muse, mutect2, varscan2
- USH1C | c.1285-7536C>A | Intron (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99139868; called by muse, mutect2, varscan2
- VN1R10P | n.659T>A | RNA (SNP) | VAF 93/204 reads (46%) | called by muse, mutect2, varscan2
- Y_RNA | chr14:50091698 G>A | 3'Flank (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
